Surgical pathology report (de-identified scan), TCGA case TCGA-33-4589, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Johns Hopkins, specimen TCGA-33-4589-01A (Primary Tumor).

FINAL DIAGNOSIS ----- Pathologist: [REDACTED]

. RIGHT LUNG (RESECTION): INFILTRATING MODERATELY WELL
DIFFERENTIATED KERATINIZING SQUAMOUS CARCINOMA. THE CARCINOMA
MEASURES 2.5 CM IN GREATEST DIMENSION AND EXTENDS TO INVOLVE THE
HILUM. CARCINOMA IN TWO (2) OF EIGHTEEN (18) PERIBRONCHIAL LYMPH
NODES. BRONCHIAL AND PLEURAL MARGINS NEGATIVE FOR TUMOR. SEE NOTE.
. LYMPH NODE LEVEL 7 (BX): ONE (1) LYMPH NODE NEGATIVE FOR TUMOR.

NOTE: We do not identify an in situ component to the carcinoma in the
lung. While this is consistent with a metastasis of the patient's
oral primary, a primary lung carcinoma cannot be ruled out.

[REDACTED]

TCGA-33-4589
[REDACTED]

Source: NCI Genomic Data Commons file 40a5a166-aff7-4910-9950-6972b30e4456 (TCGA-33-4589.F77F14E6-C17D-4908-A5E3-77D1E11F26C9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).